Somatic mutation profile of tumor specimen C3N-01904-02 (aliquot CPT0381430009) from CPTAC case C3N-01904, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Oncocytoma; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G1; Age at diagnosis: 56.1 years (20,486 days).
Specimen C3N-01904-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 88b3baab-cfc8-416e-bf9a-ddef280a37bb.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-01904-31 (Blood Derived Normal), aliquot CPT0381540002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/607b036d-dc55-4d6b-a588-d965aaa1b9bd

The open-access MAF lists 7 somatic variants for this specimen: 5 protein-altering or splice-affecting, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 5, 5'UTR 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CACNA1B | c.1027G>A p.G343S | Missense Mutation (SNP) | VAF 62/278 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV53124706, COSV53143006; called by muse, mutect2, varscan2
- SIRT4 | c.671G>A p.G224E | Missense Mutation (SNP) | VAF 70/406 reads (17%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.927); catalogued as rs767356067; called by muse, mutect2, varscan2
- EMILIN2 | c.2111G>A p.G704D | Missense Mutation (SNP) | VAF 8/92 reads (9%) | SIFT tolerated (0.42); PolyPhen benign (0.007); called by muse, mutect2
- MS4A18 | c.380C>A p.T127N | Missense Mutation (SNP) | VAF 53/179 reads (30%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.934); called by muse, mutect2, varscan2
- PHLDA1 | c.767T>A p.M256K | Missense Mutation (SNP) | VAF 53/347 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.922); called by muse, mutect2, varscan2
- PLXNC1 | c.-9C>T | 5'UTR (SNP) | VAF 16/66 reads (24%) | catalogued as rs1490680832; called by muse, mutect2
- TUBE1 | c.-11G>A | 5'UTR (SNP) | VAF 49/237 reads (21%) | catalogued as rs1554317592; called by muse, mutect2, varscan2
